CCDI case PBCNGZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/99c4144e-b484-422a-a9c4-e1b11d3c0fde

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 15.1 years (5,529 days).

Biospecimens (1 sample)
- Sample 0DWGJH: Tissue type: Tumor; Specimen type: Solid Tissue.
